Gene-level copy-number profile of tumor specimen TCGA-37-A5EL-01A from TCGA case TCGA-37-A5EL, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.0 years (19,371 days).
Specimen TCGA-37-A5EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.261c5cd1-d878-4a64-8f8a-e43b0dd69b7e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-A5EL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3eeaef9-3889-4ac1-b48b-384a0adc9ce2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 293; copy number 2: 147; copy number 3: 17,449; copy number 4: 4,252; copy number 5: 8,851; copy number 6: 12,944; copy number 7: 6,577; copy number 8: 3,450; copy number 9: 1,152; copy number 10: 1,233; copy number 11: 460; copy number 12: 840; copy number 13: 645; copy number 14: 1,093; copy number 15: 44; copy number 16: 21; copy number 18: 30; copy number 20: 19; copy number 21: 51; copy number 23: 112; copy number 25: 106; copy number 27: 32; copy number 35: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-37-A5EL-01A-11D-A26L-01): tumor purity 0.77, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:79,077,376–79,110,882, 3 genes: AC009145.3, AC009145.1, AC009145.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 13,570 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–159,147,096, 709 genes, copy number 7 (broad region; genes not listed).
- chr1:159,704,983–194,352,426, 683 genes, copy number 7–27 (broad region; genes not listed).
- chr2:38,814–79,185,523, 1,354 genes, copy number 8–14 (broad region; genes not listed).
- chr2:79,269,905–79,292,878, 1 gene, copy number 10: AC011754.2.
- chr2:98,761,098–115,940,291, 353 genes, copy number 8 (broad region; genes not listed).
- chr2:168,834,132–217,336,120, 794 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr2:217,799,588–222,044,994, 125 genes, copy number 8 (broad region; genes not listed).
- chr3:93,843,764–126,357,408, 506 genes, copy number 8 (broad region; genes not listed).
- chr3:131,026,850–131,350,465, 1 gene, copy number 11 (within-gene range 6–11): NEK11.
- chr3:131,325,092–198,222,513, 1,154 genes, copy number 9–14 (broad region; genes not listed).
- chr4:59,903,404–64,433,215, 26 genes, copy number 20–35: AC092596.1, AC097655.1, LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11, EXOC5P1, AC097491.1, LARP1BP1, AC093730.1, TECRL, RNU6-191P, DPP3P1.
- chr5:58,198–11,904,446, 242 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr6:42,879,616–48,214,794, 133 genes, copy number 16–23 (broad region; genes not listed).
- chr6:49,550,646–60,546,660, 147 genes, copy number 11–25 (within-gene range 3–25) (broad region; genes not listed).
- chr7:70,972–13,751,920, 245 genes, copy number 14 (within-gene range 3–14) (broad region; genes not listed).
- chr7:12,922,545–63,241,645, 843 genes, copy number 12–14 (broad region; genes not listed).
- chr7:78,939,850–159,233,377, 1,520 genes, copy number 7–9 (broad region; genes not listed).
- chr8:25,459,199–33,600,023, 164 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:33,641,581–33,641,939, 1 gene, copy number 7: BUD31P1.
- chr9:60,914,407–138,203,325, 1,541 genes, copy number 7–10 (broad region; genes not listed).
- chr10:44,712–2,098,269, 33 genes, copy number 7: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P.
- chr13:104,814,327–105,702,689, 7 genes, copy number 9: RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1.
- chr15:96,354,237–101,933,350, 134 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr16:46,469,341–60,053,973, 354 genes, copy number 10–15 (broad region; genes not listed).
- chr17:26,981,694–54,703,430, 1,219 genes, copy number 7 (broad region; genes not listed).
- chr18:47,390–32,938,316, 580 genes, copy number 7–8 (broad region; genes not listed).
- chr18:32,954,075–32,957,998, 1 gene, copy number 8: AC090371.1.
- chr20:35,928,570–64,313,132, 700 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 293. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
